Gene-level copy-number profile of tumor specimen TCGA-OR-A5J8-01A from TCGA case TCGA-OR-A5J8, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 66.4 years (24,266 days).
Specimen TCGA-OR-A5J8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.f857dc5c-69e3-4980-89df-44a20c0098a7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5J8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a13e56bd-8050-4371-87bc-5ff72ddd4335

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 141; copy number 2: 1,660; copy number 3: 15,188; copy number 4: 30,114; copy number 5: 4,742; copy number 6: 2,880; copy number 7: 4,063; copy number 8: 708; copy number 9: 209; copy number 10: 16; copy number 12: 91.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5J8-01A-11D-A29H-01): tumor purity 0.76, ploidy 1.23, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 141 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:240,775,514–241,357,230, 1 gene (within-gene range 0–4): RGS7.
- chr1:240,919,653–241,677,376, 12 genes (within-gene range 0–4): HNRNPA1P42, AL590682.1, MIR3123, AL592076.1, AL359764.1, AL359764.2, AL359764.3, FH, KMO, OPN3, CHML, AL133390.1.
- chr15:19,878,555–22,282,872, 128 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 316 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:10,064,243–16,192,709, 83 genes, copy number 12 (broad region; genes not listed).
- chr6:44,809,317–45,377,953, 1 gene, copy number 9 (within-gene range 4–9): SUPT3H.
- chr6:45,097,496–45,197,770, 4 genes, copy number 9: AL138880.2, RBM22P4, AL138880.1, MIR586.
- chr6:45,421,079–45,422,005, 1 gene, copy number 9: AL096865.1.
- chr6:105,679,378–113,433,555, 158 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr6:142,526,455–145,311,092, 43 genes, copy number 9 (within-gene range 7–9): AL359313.1, AL355337.1, AL023584.1, HIVEP2, AL023584.2, AL355304.1, LINC01277, AL023581.2, AIG1, AL023581.1, AL136116.2, AL136116.1, AL136116.3, AL031320.1, ADAT2, TUBB8P2, RNA5SP221, PEX3, AL031320.2, VDAC1P8, FUCA2, PHACTR2, PHACTR2-AS1, AL049844.1, LTV1, AL049844.3, AL049844.2, ZC2HC1B, PLAGL1, HYMAI, AL109755.2, AL109755.1, SF3B5, MRPL42P3, STX11, TPT1P4, AL024474.1, UTRN, AL024474.2, AL590704.1, AL513475.1, AL513475.2, AL023283.1.
- chr6:145,463,238–145,492,092, 2 genes, copy number 9: RNU1-33P, AL031119.1.
- chr7:81,946,444–85,636,344, 24 genes, copy number 10–12 (within-gene range 7–12): CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
